Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A25M, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A25M-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS -----

1) THYROID (THYROIDECTOMY):

SPECIMEN TYPE:

Total thyroidectomy

TUMOR SITE:

Right lobe

HISTOLOGIC TYPE:

Papillary carcinoma involving thyroid capsule

TUMOR SIZE:

2.5 cm greatest dimension (grossly)

FOCALITY:

Unifocal

LYMPH NODES:

Metastatic carcinoma in 1 of 2 lymph nodes

EXTENT OF INVASION

PRIMARY TUMOR:

pT2: Tumor >2 cm but <4 cm, limited to thyroid

NODAL STATUS

N1

DISTANT METASTASIS:

pMX: Cannot be assessed

MARGINS:

Margins are uninvolved

Distance of invasive carcinoma from nearest margin: 1 mm (posterior margin)

VENOUS/LYMPHATIC INVASION:

Absent

ICD-0-3

carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9

per
5/4/11

[page 2 of 2]
PART #1: TOTAL THYROID

Dictated:

The specimen is received fresh labeled with the patient's name, xxxx and is designated 'total thyroid'. The specimen has been previously oriented with a stitch marking the right thyroid tumor. The total thyroid weight is 24.14 gm and measures 8.1 x 7.0 x 2.0 cm. The left lobe measures 4.4 x 2.7 x 0.3 cm, while the right lobe measures 6.0 x 2.5 x 2.0 cm. The uninvolved thyroid parenchyma is beefy red with no obvious lesions. There is a suture marking the 'right thyroid tumor'. The anterior aspect of the specimen is inked orange while the posterior aspect is inked black. Serial sectioning reveals a lesion size of 2.5 x 2.0 x 2.0 cm in the right inferior lobe. This tumor is relatively well circumscribed with a variegated white-yellow appearance which is firm on palpation. A portion of this tumor is harvested by the tissue bank. Photographs are taken. Representative sections are submitted.

SUMMARY OF SECTIONS

- 1 - A - 1 (RIGHT SUPERIOR THYROID LOBE)
- 1 - B - 1 (RIGHT INFERIOR THYROID LOBE)
- 4 - D-F - 1 EACH (ENTIRE TUMOR SECTIONED FROM SUPERIOR TO INFERIOR IN RELATION TO NORMAL THYROID)
- 1 - G - 1 (ISTHMUS)
- 1 - H - 1 (LEFT SUPERIOR THYROID LOBE)
- 1 - I - 1 (LEFT INFERIOR THYROID LOBE)
- 9 - TOTAL - 9

Source: NCI Genomic Data Commons file 5d2e16e1-3093-4b0a-9ee4-124144ac973f (TCGA-ET-A25M.9140CD19-069D-4F54-82C8-6823CE2C2914.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).